Somatic mutation profile of tumor specimen TARGET-15-SJMPAL040036-03A.2 (aliquot TARGET-15-SJMPAL040036-03A.2-01D) from TARGET case TARGET-15-SJMPAL040036, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.4 years (1,983 days).
Specimen TARGET-15-SJMPAL040036-03A.2: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03ab6434-c6cd-4588-989d-ce27769e8fc9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL040036-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL040036-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3fd574a-1f9f-49aa-9634-5ef7034468a5

The open-access MAF lists 16 somatic variants for this specimen: 14 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Nonsense Mutation 3, Frame Shift Ins 2, RNA 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.15061C>T p.R5021* | Nonsense Mutation (SNP) | VAF 31/78 reads (40%) | catalogued as rs587783695, CM122109, COSV56415919; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FCN2 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.931); catalogued as rs767686429; called by muse, mutect2, varscan2
- OLFM2 | c.1253C>T p.S418L | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1233551999; called by muse, mutect2
- OPLAH | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as rs781820857, COSV101470796; called by muse, varscan2
- PLAAT1 | c.389G>A p.R130H (on ENST00000650797; = p.R25H on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as rs150318874; called by muse, mutect2, varscan2
- RYR2 | c.7201C>A p.R2401S | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63657786; called by muse, mutect2
- SPAG16 | c.1235C>A p.S412* | Nonsense Mutation (SNP) | VAF 3/34 reads (9%) | catalogued as COSV59097042; called by muse, mutect2
- TNIP3 | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as rs778852023, COSV50249949; called by muse, mutect2, varscan2
- WT1 | c.1072delinsGG p.R358Gfs*15 | Frame Shift Ins (INS) | VAF 49/127 reads (39%) | catalogued as COSV60069873, COSV60081928; called by pindel, varscan2*
- LONRF3 | c.502C>A p.P168T | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NTN1 | c.1307G>A p.R436H | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RUNX1 | c.540_541insAGGG p.Q181Rfs*6 (on ENST00000344691 / NM_001001890.3; = p.Q208Rfs*6 on NM_001754.5) | Frame Shift Ins (INS) | VAF 17/37 reads (46%) | called by mutect2, pindel, varscan2
- SLC4A7 | c.2865G>T p.L955F | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- VSTM2A | c.38T>C p.F13S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ZNF415 | c.339C>T p.A113= | Silent (SNP) | VAF 19/33 reads (58%) | called by muse, mutect2, varscan2
- AGAP7P | n.2051G>A | RNA (SNP) | VAF 6/100 reads (6%) | catalogued as rs560889711; called by muse, mutect2
